Somatic mutation profile of tumor specimen TCGA-HT-7691-01A (aliquot TCGA-HT-7691-01A-11D-2253-08) from TCGA case TCGA-HT-7691, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 31.4 years (11,465 days).
Specimen TCGA-HT-7691-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b02fbde1-fc50-4a0e-b549-28cb390550c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7691-10A (Blood Derived Normal), aliquot TCGA-HT-7691-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/826230e9-12f9-4d9e-9181-1a809163c9a4

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNS | c.652A>G p.I218V | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV50440083; called by muse, mutect2, varscan2
- PCDHB10 | c.563G>T p.G188V | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV53377168; called by muse, mutect2, varscan2
- SACS | c.9409G>A p.D3137N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV66537785; called by muse, mutect2, varscan2
- MRC1 | c.622T>C p.Y208H | Missense Mutation (SNP) | VAF 11/264 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2
- BRAT1 | c.732G>T p.V244= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as rs757619055, COSV61394821; called by muse, mutect2
- IL12RB1 | c.825G>A p.A275= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs141737618; called by muse, mutect2, varscan2
